Somatic mutation profile of tumor specimen TARGET-30-PATRMB-01A (aliquot TARGET-30-PATRMB-01A-01D) from TARGET case TARGET-30-PATRMB, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.0 years (1,087 days).
Specimen TARGET-30-PATRMB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0360830-1659-41fc-85a9-93f31b790652.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATRMB-10A (Blood Derived Normal), aliquot TARGET-30-PATRMB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/720c828c-13c8-48a0-8ed5-7a82e9102a96

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3397G>T p.D1133Y | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745437003, COSV59258094; called by muse, mutect2, varscan2
- SIN3A | chr15:75369975 C>A | 3'Flank (SNP) | VAF 73/156 reads (47%) | catalogued as COSV51226905; called by muse, mutect2, varscan2
